Gene-level copy-number profile of tumor specimen TCGA-GR-7351-01A from TCGA case TCGA-GR-7351, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 57.0 years (20,812 days).
Specimen TCGA-GR-7351-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.3da2d7e4-c2e6-4b54-a9d7-425dd7da9ab0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GR-7351-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 842 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ccff94da-409c-4b80-badb-52ad17d78b98

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,097; copy number 2: 51,913; copy number 3: 2,453; copy number 4: 318.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GR-7351-01A-11D-2209-01): tumor purity 0.59, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,676. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
